Somatic mutation profile of tumor specimen TCGA-GU-A762-01A (aliquot TCGA-GU-A762-01A-11D-A339-08) from TCGA case TCGA-GU-A762, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 87.1 years (31,812 days).
Specimen TCGA-GU-A762-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4411b96f-ed0c-4d2b-aa26-854bb9f3d1bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GU-A762-10A (Blood Derived Normal), aliquot TCGA-GU-A762-10A-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48864ad7-4bad-4427-beec-d44aec6d75d7

The open-access MAF lists 115 somatic variants for this specimen: 86 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 27, Nonsense Mutation 9, Frame Shift Del 7, RNA 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1088G>C p.C363S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876660556, CD064635, COSV61684006, COSV61691764, COSV61695842; called by muse, mutect2, varscan2
- AASDH | c.3058G>T p.V1020F | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1347018728, COSV52711377; called by muse, mutect2, varscan2
- ABO | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as rs781806838; called by muse, mutect2
- ACIN1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52983063; called by muse, mutect2, varscan2
- ADAD1 | c.139T>A p.S47T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as COSV56647889; called by muse, mutect2, varscan2
- ADNP | c.2809G>A p.E937K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs184697035, COSV62425042; called by muse, mutect2, varscan2
- AKR1C1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs138128200; called by muse, mutect2, varscan2
- AOC2 | c.683C>G p.S228* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as COSV99513564; called by muse, mutect2, varscan2
- ARL4A | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63319714; called by muse, mutect2, varscan2
- BCL9L | c.2221G>T p.E741* | Nonsense Mutation (SNP) | VAF 38/146 reads (26%) | catalogued as COSV99418954; called by muse, mutect2, varscan2
- BEND4 | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV72469483; called by muse, mutect2, varscan2
- CACNG7 | c.202G>C p.E68Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.289); catalogued as COSV55817810, COSV99712384; called by muse, mutect2, varscan2
- CCT6B | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV58492399; called by muse, mutect2, varscan2
- CDC42EP4 | c.944C>G p.S315* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV100231786, COSV59962371; called by muse, mutect2, varscan2
- CDH17 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs771839915, COSV50344779; called by muse, mutect2, varscan2
- CHST15 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.076); catalogued as rs761889134, COSV60566386; called by muse, mutect2, varscan2
- CLCNKB | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV65162054; called by muse, mutect2
- COG4 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as rs770474800, COSV56791647; called by muse, mutect2, varscan2
- CTNND2 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as rs764657493, COSV100470772, COSV58878402; called by muse, mutect2, varscan2
- DACH1 | c.1373A>T p.N458I (on ENST00000619232 / NM_001366712.1; = p.N406I on NM_080759.6) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57522261; called by muse, mutect2, varscan2
- DOCK5 | c.5297G>A p.S1766N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV52413325; called by muse, mutect2, varscan2
- EGF | c.1184G>A p.C395Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54485781; called by muse, mutect2, varscan2
- EPHA5 | c.2110G>T p.V704L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV56679260; called by muse, mutect2, varscan2
- FBN1 | c.1196C>A p.P399Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57332732; called by muse, mutect2, varscan2
- FBN3 | c.3214G>A p.V1072M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs769766254, COSV54475173; called by muse, mutect2, varscan2
- FLG | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV64251453; called by muse, mutect2, varscan2
- GOLGB1 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61472146; called by muse, mutect2, varscan2
- GSTA2 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs201934364, COSV72415657; called by muse, mutect2, varscan2
- GYG1 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56051462; called by muse, mutect2, varscan2
- HECTD4 | c.8504G>A p.R2835Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs753525697, COSV66401110; called by muse, mutect2, varscan2
- HKDC1 | c.1535T>G p.L512R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63579946; called by muse, mutect2, varscan2
- HRH3 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58048944; called by muse, mutect2, varscan2
- ICE2 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV55034466; called by muse, mutect2, varscan2
- ITPK1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.605); catalogued as COSV50901098, COSV99968939; called by muse, mutect2, varscan2
- JADE2 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50912117; called by muse, mutect2, varscan2
- KIAA1210 | c.2126G>C p.S709T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV68180739; called by muse, mutect2, varscan2
- KLHL2 | c.1276del p.E426Sfs*5 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | catalogued as COSV56983750, COSV99899970; called by mutect2, pindel, varscan2
- KMT2D | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | catalogued as COSV99976571; called by muse, mutect2, varscan2
- KRTAP5-1 | c.126C>A p.C42* | Nonsense Mutation (SNP) | VAF 32/258 reads (12%) | catalogued as COSV101192878, COSV101192954; called by muse, mutect2, varscan2
- LNPEP | c.1488C>G p.F496L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV51482004; called by muse, mutect2, varscan2
- LRP8 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773368152, COSV60101615; called by muse, mutect2
- LRRK2 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as COSV54174330; called by muse, mutect2, varscan2
- MMP9 | c.1697A>G p.K566R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV63434615; called by muse, varscan2
- MTM1 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs782444216, COSV60338058; called by muse, mutect2
- MX2 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV58100172; called by muse, mutect2, varscan2
- NUDT11 | c.128A>G p.D43G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV101047025; called by muse, mutect2, varscan2
- NUP214 | c.2348G>C p.R783T | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV63913646; called by muse, mutect2, varscan2
- OPCML | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV59455433; called by muse, mutect2
- PAQR3 | c.322T>C p.C108R | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV55012441; called by muse, mutect2, varscan2
- PCNX4 | c.2884G>T p.A962S (on ENST00000406854 / NM_001330177.2; = p.A728S on NM_022495.5) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as COSV58303969, COSV58308961; called by muse, mutect2, varscan2
- PDZD7 | c.1480G>A p.G494R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777039039, COSV64647875; called by muse, mutect2, varscan2
- PSG2 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 68/395 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs768618168, COSV61546056; called by muse, mutect2, varscan2
- PSMD11 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55577904, COSV55581709; called by muse, mutect2, varscan2
- RAP1GDS1 | c.676G>T p.E226* (on ENST00000408927 / NM_001100427.2; = p.E227* on NM_021159.5) | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV99216803; called by muse, mutect2, varscan2
- RHAG | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100006465, COSV57705766; called by muse, mutect2, varscan2
- RIC1 | c.3707C>G p.S1236C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV99316961; called by muse, mutect2
- RIMBP2 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs950774501, COSV55470312; called by muse, mutect2, varscan2
- RXYLT1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV104370798, COSV54170365; called by muse, mutect2, varscan2
- SDF2 | c.606G>T p.L202F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV55932495; called by muse, varscan2
- SDF2 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55932501, COSV99897992; called by muse, varscan2
- SHOX2 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55841243; called by muse, mutect2, varscan2
- SLC19A1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs1013303201, COSV60758291; called by muse, mutect2, varscan2
- SLC22A12 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV60574455; called by muse, mutect2, varscan2
- SND1 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV100690032; called by muse, mutect2, varscan2
- SNX30 | c.869T>G p.L290W | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV65294515; called by muse, mutect2, varscan2
- SPACA7 | c.160C>A p.L54M | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52101848; called by mutect2, varscan2
- STAB1 | c.3946C>T p.Q1316* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100401446; called by muse, mutect2, varscan2
- TBC1D31 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV54871701; called by muse, mutect2, varscan2
- THBS1 | c.2959G>A p.V987I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs778612797, COSV99527749; called by muse, mutect2, varscan2
- TMED6 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54743748, COSV99650633; called by muse, mutect2, varscan2
- TTN | c.51998C>T p.A17333V (on ENST00000591111; = p.A9909V on NM_003319.4) | Missense Mutation (SNP) | VAF 23/184 reads (13%) | PolyPhen benign (0.367); catalogued as rs1336627311, COSV60399810; called by muse, mutect2, varscan2
- UPF2 | c.3046G>A p.D1016N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV62664528; called by muse, mutect2, varscan2
- USP25 | c.1442C>A p.S481Y | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.353); catalogued as COSV53491287; called by muse, mutect2, varscan2
- ZNF385D | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779277619, COSV55778576; called by muse, mutect2, varscan2
- ZNF527 | c.1705C>G p.L569V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV62236521; called by muse, mutect2, varscan2
- ZNF536 | c.3330C>A p.D1110E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); catalogued as COSV62836161; called by muse, mutect2, varscan2
- ZNF623 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV71697386; called by muse, mutect2, varscan2
- ZNF99 | c.1080G>T p.E360D | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV68057244; called by muse, mutect2, varscan2
- ARMH3 | c.390_406del p.F130Lfs*19 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel
- BASP1 | c.524del p.G175Afs*49 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- FAT1 | c.1477_1478del p.G493* | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | called by mutect2, pindel, varscan2
- NTMT1 | c.625_626dup p.N209Kfs*15 | Frame Shift Ins (INS) | VAF 24/118 reads (20%) | called by mutect2, pindel, varscan2
- PXT1 | c.264_271delinsA p.H88Qfs*21 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | called by pindel, varscan2*
- TRAV5 | c.169A>C p.K57Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- VEZT | c.462del p.S155Afs*20 | Frame Shift Del (DEL) | VAF 51/284 reads (18%) | called by mutect2, pindel, varscan2
- ZBP1 | c.1107_1135del p.D370Rfs*38 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- AHNAK | c.16992C>A p.P5664= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV57234285; called by muse, mutect2, varscan2
- ASPRV1 | c.426C>G p.L142= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV57228113; called by muse, mutect2, varscan2
- BCAR3 | c.78C>T p.D26= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53080021; called by muse, mutect2, varscan2
- CALML5 | c.313C>A p.R105= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs368824145; called by muse, mutect2, varscan2
- CDC42BPB | c.4044G>T p.V1348= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1274709312, COSV63473863, COSV63475807; called by muse, mutect2, varscan2
- CPD | c.486C>T p.R162= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs780850763, COSV56716961; called by muse, mutect2, varscan2
- DLGAP1 | c.952C>T p.L318= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV59841782; called by muse, mutect2, varscan2
- DMXL1 | c.6336G>A p.L2112= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV60722660; called by muse, mutect2, varscan2
- GOLGB1 | c.1005C>T p.F335= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV61472152; called by muse, mutect2, varscan2
- GRIN2A | c.3192G>T p.T1064= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs748790515, COSV58038769, COSV58049654, COSV58059379; called by muse, mutect2, varscan2
- IGHV3-35 | c.117C>A p.L39= | Silent (SNP) | VAF 43/185 reads (23%) | called by muse, mutect2, varscan2
- KCTD19 | c.1032C>T p.S344= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs777176067, COSV58575433; called by muse, mutect2
- LILRA2 | c.1039C>A p.R347= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52193758, COSV52198428; called by muse, varscan2
- LRRC59 | c.618C>G p.L206= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as rs758251033, COSV56815777; called by muse, mutect2, varscan2
- MRGPRF | c.186C>T p.N62= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs756175408, COSV100307805; called by muse, mutect2
- NTM | c.942C>T p.G314= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs184652868, COSV66216801; called by muse, mutect2, varscan2
- OPCML | c.426C>T p.S142= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV59455417; called by muse, mutect2
- PIK3C2G | c.417C>T p.S139= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV56837783; called by muse, mutect2, varscan2
- PTCHD3 | c.348C>A p.T116= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV71257320; called by muse, mutect2, varscan2
- SCN10A | c.195G>A p.K65= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as rs138298994; called by muse, mutect2, varscan2
- SFMBT1 | c.2007G>A p.K669= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV56258073; called by muse, varscan2
- SGK3 | c.1044G>A p.G348= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1413555735, COSV61897369; called by muse, mutect2, varscan2
- SLC7A4 | c.384C>T p.I128= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs369802595; called by muse, mutect2, varscan2
- THAP9 | c.489G>A p.K163= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV56358140; called by muse, mutect2, varscan2
- TPTE | c.1413T>A p.P471= (on ENST00000618007 / NM_199261.4; = p.P453= on NM_199259.4) | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- XPO1 | c.1071A>T p.V357= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV68948171; called by muse, mutect2, varscan2
- ZNF707 | c.957C>T p.A319= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV62311834; called by muse, mutect2, varscan2
- CMAS | c.*2A>C | 3'UTR (SNP) | VAF 18/46 reads (39%) | catalogued as rs895013720, COSV99982606; called by muse, varscan2
- TMEM183B | n.62G>C | RNA (SNP) | VAF 7/30 reads (23%) | catalogued as rs1319589362; called by muse, mutect2, varscan2
